TCGA case TCGA-L5-A8NR — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/da33c637-e9db-4a67-9198-2eda750dead7

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 81.4 years (29,730 days); Year of diagnosis: 2001; Method of diagnosis: Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 265 days; Cancer detection method: Symptomatic; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 7; Lymph nodes tested: 10.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 82.1 years (29,995 days); Days to diagnosis: 265 days; Prior treatment: Yes.

Follow-up (1 entry)
- Day 265 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 265 days; Evidence of progression type: Convincing Image Source.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 157 cm; BMI: 24.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Medically Treated; Risk factors: GERD.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Tobacco smoking quit year: 1971; Age at onset: 21.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L5-A8NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-L5-A8NR-01A-01-TS1: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-L5-A8NR-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-L5-A8NR-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: michigan; Cancer procurement city: ann arbor; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 3; Alcohol history documented: No; History reflux disease indicator: Yes; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 265 days; disease-specific survival: no event (censored), 265 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 265 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-L5-A8NR-01A-11D-A37B-01): tumor purity 0.67, ploidy 2.87, whole-genome doublings 1.
